Somatic mutation profile of tumor specimen MP2PRT-PAUYZG-TMP1-A (aliquot MP2PRT-PAUYZG-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUYZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.7 years (2,097 days).
Specimen MP2PRT-PAUYZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51c7353c-55b1-4414-be32-11924abbbadc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYZG-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7001d3d9-1d85-43c8-9d27-8b223d03c1c3

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EMID1 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 208/496 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.267); catalogued as COSV61828800; called by muse, mutect2, varscan2
- FGF23 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 256/952 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs767171941, COSV99426364; called by muse, mutect2, varscan2
- IGHMBP2 | c.721del p.C241Afs*44 | Frame Shift Del (DEL) | VAF 110/328 reads (34%) | catalogued as CM034528; called by mutect2, pindel, varscan2
- NOS1 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 172/395 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs370868180; called by muse, mutect2, varscan2
- OR6N1 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 172/412 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.05); catalogued as COSV100625286; called by muse, mutect2, varscan2
- PLEKHA7 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs374946956; called by muse, mutect2, varscan2
- SETD1B | c.5569G>A p.V1857M | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99930948; called by muse, mutect2, varscan2
- SLPI | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 175/440 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs373520449, COSV58092557; called by muse, mutect2, varscan2
- LTBP4 | c.2684del p.L895Pfs*198 (on ENST00000308370 / NM_001042544.1; = p.L858Pfs*198 on NM_003573.2) | Frame Shift Del (DEL) | VAF 31/260 reads (12%) | called by pindel*, varscan2
- PLXNB1 | c.4010G>A p.C1337Y | Missense Mutation (SNP) | VAF 149/419 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBA2 | c.1370_1376delinsCCCG p.H457_V459delinsPR | In Frame Del (DEL) | VAF 78/299 reads (26%) | called by pindel, varscan2*
- C6orf118 | c.165C>T p.D55= | Silent (SNP) | VAF 171/407 reads (42%) | catalogued as rs760006970, COSV57815514, COSV57815652; called by muse, mutect2, varscan2
- IGHV4-59 | c.350delinsCGAACCCC p.*117delinsANP | Silent (INS) | VAF 77/225 reads (34%) | called by pindel, varscan2*
- OR10G7 | c.117G>C p.G39= | Silent (SNP) | VAF 160/478 reads (33%) | catalogued as COSV100390048; called by muse, mutect2
